Gene-level copy-number profile of tumor specimen HCM-SANG-0285-C18-08A-01D-A80T-32 from HCMI case HCM-SANG-0285-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0285-C18-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d498fd1b-f979-4bcc-bb67-b116e60c5866.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0285-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/ac56740f-ec76-4419-928d-bb15cb2da878

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 524; copy number 2: 43,743; copy number 3: 10,555; copy number 4: 4,064; copy number 5: 12; copy number 6: 2; copy number 8: 4.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:14,137,146–14,171,267, 1 gene (within-gene range 0–2): AC022098.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,154,985–245,709,432, 1 gene, copy number 5 (within-gene range 4–5): KIF26B.
- chr1:245,614,773–246,507,312, 8 genes, copy number 5 (within-gene range 4–5): AC104462.2, AC104462.1, SMYD3, AC118555.1, SMYD3-AS1, CHCHD4P5, RNU6-1283P, SMYD3-IT1.
- chr2:89,330,110–89,600,680, 2 genes, copy number 6: IGKV2-40, 5S_rRNA.
- chr8:143,280,161–143,299,952, 3 genes, copy number 5: MINCR, ZNF696, AC138696.2.
- chr20:30,484,925–30,816,274, 4 genes, copy number 8: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.

Autosomal genes at a single copy (total copy number 1): 524. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
